TCGA case TCGA-YA-A8S7 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Spectrum Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bb2069d3-e699-4a8a-bb61-b3c28b98a66b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 412 days (1.1 years).

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,188 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 70.1 years (25,586 days); Days to diagnosis: 398 days (1.1 years); Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Brain, NOS. Age at diagnosis: 70.1 years (25,586 days); Days to diagnosis: 398 days (1.1 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 398 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to recurrence: 398 days (1.1 years).
- Day 398 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 398 days (1.1 years).
- Days to follow up: 412 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.3].
- Albumin 2.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 3.8 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1].
- Alpha Fetoprotein 56 ng/mL [Blood test normal range upper: 8].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.2 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis C Infection.
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 164 cm; BMI: 27.1.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YA-A8S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-YA-A8S7-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-YA-A8S7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YA-A8S7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Surgical procedure other: Right Hepatectomy; Hepatic inflammation adj tissue: Mild.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 412 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 412 days; disease-free interval: event (new tumor event after initially disease-free), 398 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 398 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YA-A8S7-01A-11D-A36W-01): tumor purity 0.36, ploidy 3.68, whole-genome doublings 1.
